Surgical pathology report (de-identified scan), TCGA case TCGA-DV-5573, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DV-5573-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS:

1. Tumor #1, right kidney (resection): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
2. Tumor #2, right kidney (resection): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
3. Tumor #3, right kidney (resection): Renal cyst
4. Tumor #4, right kidney (resection): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
5. Tumor #5, right kidney (resection): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
6. Tumor #6, right kidney (resection): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II
7. Rib, 11th, right (resection): Gross examination only

NOTE:

CLINICAL INFORMATION: Allocate Order to Protocol: [REDACTED] Brief Clinical History: VHL with multiple tumors in right kidney. Specimen Taken For Protocol: [REDACTED] -
Yes

Patient Identification

1

[page 2 of 3]
PROCEDURE: Pre-Operative Diagnosis: multiple tumors in right kidney
Post-Operative Diagnosis: same Operative Findings: 6 tumors removed from right kidney.

SPECIMENS SUBMITTED: 1. TUMOR, # 1
2. TUMOR, # 2
3. TUMOR, # 3
4. TUMOR, # 4
5. TUMOR, # 5
6. TUMOR, # 5
7. RIB, 11th rib

GROSS DESCRIPTION: Received are 7 formalin-filled containers labeled with the patient's name, medical record number, and further described as follows:

1. "Tumor #1" are two yellow/brown tissue fragments, each measuring 0.5 x 0.5 x 0.5 cm. Both specimens are wrapped in lens paper and entirely submitted in a white cassette labeled [REDACTED] for permanent processing.
2. "Tumor #2" is a yellow/brown piece of tissue measuring 0.8 x 0.8 x 0.8 cm. 50% is procured for Research. In Surgical Pathology, the remainder of the specimen is received and is consistent with the above description. The specimen is placed in a filter bag and placed in a white cassette labeled [REDACTED] #2 for permanent processing.
3. "Tumor #3" is a white/tan/red piece of tissue measuring 1 cm in diameter consistent with a cyst wall". The specimen is serially sectioned and entirely submitted in a white cassette labeled [REDACTED] #3 for permanent processing.
4. "Tumor #4" is a brown and yellow piece of tissue measuring 2 x 1.5 x 1.2 cm. 50% is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The specimen is serially sectioned and entirely submitted in a white cassette labeled [REDACTED] #4 for permanent processing.
5. "Tumor #5" is a tan/brown/yellow piece of tissue 3.2 x 3.0 x 3.0 cm. 85% is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The specimen is serially sectioned and entirely submitted in a white cassette [REDACTED] -B for permanent processing.
6. "Tumor #6" is a tan/brown piece of tissue measuring 2.8 x 2.2 x 2.1 cm. The specimen is sectioned revealing a mostly homogeneous surface with slightly hemorrhagic areas. 85% of the specimen is procured for Research. The specimen is received in Surgical Pathology and is consistent with the above description. The specimen is serially sectioned and entirely submitted in a white cassettes labeled [REDACTED] -B for permanent processing.

Patient Identification

[page 3 of 3]
7. "Rib, 11th" is a white/tan 3.0 x 2.0 x0.8 cm piece of rib with some adherent tan soft tissue. No mass lesions are identified. The specimen is kept for gross examination only.

No consultants

Patient Identification
f

Source: NCI Genomic Data Commons file d9bbb1ef-af2d-420b-b4f3-f4fadfd2e4cd (TCGA-DV-5573.534D2539-D570-4782-B7D8-2C489BE26D19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).